Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1XG, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1XG-01A (Primary Tumor).

Department of Cancer Pathology

copy No.

Date:

Examination: Histopathological examination

Internal invoice No.

Value of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender: F

Material: 1. Total organ resection – right breast *

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination: up to 8 working days

Clinical diagnosis: Cancer of the right breast, ulcerous – Toilett mastectomy.

ICD-O-3
carcinoma, infiltrating duct, nos 8500/
Site: breast, nos C50.9 h 4/12/11

Examination performed on:

Macroscopic description:

Right breast sized 13.7 x 7.6 x 4.8 cm removed without axillary tissues and with a skin flap of 17.8 x 10.2 cm. Weight 193 g.
Tumour sized 6.2 x 4.3 x 7.8 cm in the middle part, 0.1 cm from the upper boundary, 0.1 cm from the base.

Microscopic description:

Carcinoma ductale invasivum - NHG3 (3+2+3/20 mitoses/10 HPF - visual area: 0.55mm).

Infiltratio carcinomatosa cutis et musculi pectoralis.

Mamilla sine laesionibus

Glandular tissue showing parenchyma atrophy.

Histopathological diagnosis:

Carcinoma ductale invasivum mammae dextrae. Invasive ductal carcinoma of the right breast.

Metastases carcinomatosa in lymphonodis axillae (No II/II). Cancer metastases of the axillary lymph nodes. (NHG3, pT4b, pN1a).

Compliance validated by

Examination performed on:

Results of immunohistochemical examination:

Estrogen receptors found in 10-75% of neoplastic cell nuclei. Progesterone receptors found in 10-75% of neoplastic cell nuclei. HER2 protein stained with HercepTest™ by DAKO.

Negative reaction in invasive cancerous cells (Score = 0)

Compliance valid:

IHPAA Discrepancy		☒

Source: NCI Genomic Data Commons file 179ff415-2be8-439b-8131-97de3912be25 (TCGA-D8-A1XG.AA869507-1B46-4812-8EC5-A4E01C588E6E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).